Gene-level copy-number profile of tumor specimen ALCH-B4B1-TTP1-A from ALCHEMIST case ALCH-B4B1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.6 years (22,509 days).
Specimen ALCH-B4B1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b4810766-923c-43b8-8820-1ec6be553136.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4B1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/d799ea23-7427-4435-9245-860bfa507ee3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 229; copy number 1: 13,286; copy number 2: 44,112; copy number 3: 1,183; copy number 4: 74; copy number 5: 8; copy number 6: 3; copy number 7: 1; copy number 9: 6.

Homozygous deletions (total copy number 0; autosomes only): 190 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,487,364–150,557,724, 5 genes (within-gene range 0–3): TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2.
- chr1:150,551,929–150,552,014, 1 gene (within-gene range 0–3): MIR4257.
- chr2:89,266,494–89,600,680, 9 genes: IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr2:90,309,230–90,315,836, 2 genes: AC233263.2, IGKV1OR2-118.
- chr2:91,578,478–91,685,884, 6 genes: AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1.
- chr2:132,253,154–132,294,377, 4 genes (within-gene range 0–1): RNA5-8SP5, MIR663B, CDC27P1, AC097532.1.
- chr3:147,386,046–147,406,809, 2 genes (within-gene range 0–1): ZIC4, ZIC4-AS1.
- chr3:184,710,364–184,740,104, 2 genes: MAGEF1, AC107294.2.
- chr3:184,741,937–184,743,284, 2 genes: AC107294.3, AC107294.1.
- chr4:48,852,008–49,589,529, 25 genes (within-gene range 0–2): OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr6:106,969,831–107,051,586, 2 genes: CD24, MTRES1.
- chr7:43,940,895–44,041,892, 9 genes (within-gene range 0–2): POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP.
- chr7:62,275,361–63,154,934, 7 genes: AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1.
- chr9:128,633,661–128,656,787, 2 genes (within-gene range 0–2): DYNC2I2, VTI1BP4.
- chr10:32,173,684–32,232,245, 3 genes: RNU7-22P, PPIAP31, RPS24P13.
- chr10:38,403,189–42,475,349, 20 genes (within-gene range 0–2): AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1, KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1.
- chr10:49,734,641–49,762,379, 1 gene: OGDHL.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.
- chr11:57,542,641–57,568,284, 2 genes: SMTNL1, UBE2L6.
- chr11:71,448,674–71,568,934, 10 genes (within-gene range 0–1): AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1.
- chr11:71,579,728–71,579,848, 1 gene (within-gene range 0–2): KRTAP5-14P.
- chr11:76,186,325–76,216,025, 3 genes: WNT11, AP000785.1, LINC02761.
- chr12:34,190,471–34,219,246, 3 genes: AC140847.2, RNA5SP357, DUX4L27.
- chr12:111,581,379–111,600,256, 2 genes (within-gene range 0–3): IFITM3P5, ATXN2-AS.
- chr13:100,062,296–100,063,601, 1 gene: ASNSP3.
- chr14:18,333,726–18,667,370, 18 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3.
- chr14:96,592,399–96,605,974, 1 gene: AL137786.1.
- chr15:64,687,573–64,719,602, 4 genes: OAZ2, AC100830.3, AC100830.2, AC100830.1.
- chr15:100,074,081–100,074,190, 1 gene (within-gene range 0–2): RNA5SP402.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr16:81,100,875–81,220,370, 3 genes: PKD1L2, RNU6-1191P, AC092718.9.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr17:36,940,049–36,943,456, 1 gene (within-gene range 0–1): AC243773.1.
- chr17:66,964,707–67,033,398, 3 genes: CACNG4, AC005544.1, AC005544.2.
- chr18:2,847,006–2,916,003, 1 gene: EMILIN2.
- chr19:27,638,483–27,794,005, 4 genes (within-gene range 0–1): ERVK-28, AC112702.1, LINC00662, AC006504.1.
- chr19:27,802,838–27,898,927, 5 genes (within-gene range 0–1): AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4.
- chr20:63,974,116–63,980,008, 1 gene (within-gene range 0–1): SAMD10.
- chr21:10,328,411–10,649,835, 11 genes: AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1.
- chr22:39,519,672–39,532,761, 2 genes: ATF4, RPS19BP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:659,862–693,352, 2 genes, copy number 5 (within-gene range 2–6): TPPP, AC026740.1.
- chr8:21,919,662–22,006,585, 1 gene, copy number 5: XPO7.
- chr8:143,816,344–143,878,467, 7 genes, copy number 5–6: PUF60, AC234917.3, AC234917.1, NRBP2, MIR6845, AC234917.2, EPPK1.
- chr11:1,947,278–1,989,920, 2 genes, copy number 6–7: MRPL23, MRPL23-AS1.
- chr19:1,228,287–1,274,880, 6 genes, copy number 9 (within-gene range 4–9): CBARP, AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1.

Autosomal genes at a single copy (total copy number 1): 10,488. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
